Somatic mutation profile of tumor specimen TCGA-A6-3807-01A (aliquot TCGA-A6-3807-01A-01W-0995-10) from TCGA case TCGA-A6-3807, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 53.7 years (19,624 days).
Specimen TCGA-A6-3807-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b655996-65cc-4921-b40c-8496a3c2630d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-3807-10A (Blood Derived Normal), aliquot TCGA-A6-3807-10A-01D-1459-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b69d114-8eb7-4fed-b2b0-999428ccdc31

The open-access MAF lists 107 somatic variants for this specimen: 80 protein-altering or splice-affecting, 21 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 21, Nonsense Mutation 6, 3'UTR 3, Intron 3, Splice Site 2, Nonstop Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 113/213 reads (53%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 110/251 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.708C>G p.Y236* | Nonsense Mutation (SNP) | VAF 148/298 reads (50%) | hotspot (GDC flag); catalogued as CD951866, COSV52713084, COSV52728511, COSV53025106, COSV53864205; called by muse, mutect2, varscan2
- ACVR1B | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as rs1286817470, COSV57777057; called by muse, mutect2, varscan2
- ADAMTS2 | c.2101G>A p.G701S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs755490840; called by muse, mutect2, varscan2
- AGXT2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 199/1017 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs778312587, COSV51484115; called by muse, mutect2, varscan2
- AKAP9 | c.11307dup p.Q3770Afs*52 (on ENST00000359028; = p.Q3746Afs*52 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 13/117 reads (11%) | catalogued as rs747796926; called by mutect2, varscan2
- ANK2 | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100003854; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV99784300; called by muse, mutect2, varscan2
- AP3B1 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV99672359; called by muse, mutect2
- ARAP2 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 148/725 reads (20%) | catalogued as COSV58282085; called by muse, mutect2, varscan2
- ATL1 | c.1552-1G>A p.X518_splice | Splice Site (SNP) | VAF 41/131 reads (31%) | catalogued as rs1231465018, COSV100220874; called by muse, mutect2, varscan2
- BRIP1 | c.3350C>G p.S1117* | Nonsense Mutation (SNP) | VAF 164/763 reads (21%) | catalogued as COSV51999167; called by muse, mutect2, varscan2
- C5orf49 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV100603924; called by muse, mutect2, varscan2
- CACNA1F | c.4672T>G p.W1558G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100545320; called by muse, mutect2, varscan2
- CDH18 | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV56905362; called by muse, mutect2, varscan2
- CDK14 | c.434C>G p.S145C (on ENST00000380050 / NM_001287135.2; = p.S127C on NM_012395.3) | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99726725; called by muse, mutect2, varscan2
- COBL | c.3352C>T p.H1118Y | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs867135548, COSV54344950; called by muse, mutect2
- COL6A3 | c.5684C>T p.S1895L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs760532694, COSV99800933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRPPA | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1258003335, COSV101235470; called by muse, mutect2, varscan2
- DMD | c.6741A>T p.K2247N | Missense Mutation (SNP) | VAF 151/715 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as CD159991, COSV58908961; called by muse, mutect2, varscan2
- DMXL1 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100224856; called by muse, mutect2, varscan2
- DPEP2 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52054539; called by muse, mutect2, varscan2
- DYNC1LI2 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99263233; called by muse, mutect2
- ESM1 | c.274T>C p.F92L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV101195712; called by muse, mutect2, varscan2
- FMR1NB | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV100975609; called by mutect2, varscan2
- GABRG1 | c.1100C>G p.T367S | Missense Mutation (SNP) | VAF 125/732 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.065); catalogued as rs746021913, COSV54953720; called by muse, mutect2, varscan2
- GALNT13 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 421/981 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV67220123; called by muse, mutect2, varscan2
- GATAD2B | c.424A>T p.M142L | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV64084054; called by muse, mutect2, varscan2
- HK1 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477873055, COSV53857658; called by muse, varscan2
- IL20RB | c.402C>G p.N134K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.109); catalogued as COSV59047813; called by muse, mutect2, varscan2
- ILDR2 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV54830741; called by muse, mutect2, varscan2
- KIAA0319 | c.2738G>A p.C913Y | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1467337732, COSV100985775; called by muse, mutect2, varscan2
- LAMA3 | c.8696T>C p.V2899A (on ENST00000313654 / NM_198129.4; = p.V1290A on NM_000227.6) | Missense Mutation (SNP) | VAF 222/995 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV99335736; called by muse, mutect2, varscan2
- LHFPL3 | c.233del p.G78Afs*25 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as COSV67814458; called by mutect2, pindel, varscan2
- LRRC3B | c.350C>A p.T117N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.381); catalogued as COSV101185682, COSV67521039; called by muse, mutect2, varscan2
- LRRN3 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100073051; called by muse, mutect2, varscan2
- MAP1B | c.3116T>A p.M1039K | Missense Mutation (SNP) | VAF 72/448 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV99702891; called by muse, mutect2, varscan2
- METTL3 | c.341A>G p.D114G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1415229310, COSV99398565; called by muse, mutect2, varscan2
- MOV10L1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 88/147 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781329843, COSV53170216; called by muse, mutect2, varscan2
- MUC17 | c.6559G>C p.D2187H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV60287802; called by muse, mutect2, varscan2
- MYL2 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 29/401 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV99960870; called by muse, mutect2
- NLK | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 232/970 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69408711; called by muse, mutect2, varscan2
- OR4K1 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 97/800 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53460010; called by muse, mutect2, varscan2
- OR52E4 | c.307A>G p.M103V | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as COSV100389362; called by muse, mutect2, varscan2
- OSBPL11 | c.2178+1G>A p.X726_splice | Splice Site (SNP) | VAF 84/456 reads (18%) | catalogued as COSV99954490; called by muse, mutect2, varscan2
- PCDH18 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 83/445 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs903210960, COSV61267146; called by muse, mutect2, varscan2
- PCDHB10 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs377570572, COSV53384523; called by muse, mutect2, varscan2
- PLXND1 | c.4880C>T p.S1627L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100140329; called by muse, mutect2, varscan2
- PNPLA3 | c.935G>A p.W312* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV99337288; called by muse, mutect2
- PRKRA | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 32/369 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV100359793; called by muse, mutect2, varscan2
- RAD50 | c.3631C>T p.L1211F | Missense Mutation (SNP) | VAF 50/356 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54751119; called by muse, mutect2, varscan2
- RELN | c.4093T>A p.F1365I | Missense Mutation (SNP) | VAF 195/938 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV100634745; called by muse, mutect2, varscan2
- RIC1 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 115/633 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99317928; called by muse, mutect2, varscan2
- RIF1 | c.4000C>G p.Q1334E | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99691144; called by muse, mutect2, varscan2
- ROBO2 | c.2795G>C p.S932T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); catalogued as COSV100169601; called by muse, mutect2
- ROS1 | c.7044A>T p.*2348Yext*1 | Nonstop Mutation (SNP) | VAF 38/169 reads (22%) | catalogued as COSV63854974; called by muse, mutect2, varscan2
- RSPH4A | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV57637028; called by muse, mutect2
- RYR2 | c.4000T>A p.L1334M | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as COSV100768904; called by muse, mutect2, varscan2
- SH2D1A | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63578913; called by muse, mutect2, varscan2
- SLC5A3 | c.1652A>T p.N551I | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV62969533; called by muse, mutect2, varscan2
- SMARCA2 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs775965236, COSV61807087; called by muse, mutect2, varscan2
- SPATA16 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 144/382 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs141658177; called by muse, mutect2, varscan2
- STAG1 | c.1996G>T p.V666L | Missense Mutation (SNP) | VAF 39/249 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV52608797; called by muse, mutect2, varscan2
- STRN4 | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1381287864, COSV52188963; called by muse, varscan2
- STX6 | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 108/659 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs776504795, COSV51111185; called by muse, mutect2, varscan2
- TAF1L | c.3728G>A p.R1243Q | Missense Mutation (SNP) | VAF 112/480 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs374466609; called by muse, mutect2, varscan2
- THOC5 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as rs914364867, COSV100803649; called by muse, mutect2, varscan2
- TNFRSF11A | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV54023323; called by muse, mutect2, varscan2
- TRHR | c.586T>G p.F196V | Missense Mutation (SNP) | VAF 174/1404 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs759864738, COSV100305153, COSV61232746; called by muse, mutect2, varscan2
- TRIM68 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV100331674, COSV56168416; called by muse, mutect2, varscan2
- UBE2R2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as rs1320272305, COSV54289167; called by muse, mutect2, varscan2
- UNC80 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs1299781997, COSV55905898; called by muse, mutect2, varscan2
- ZNF99 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as COSV101233942, COSV68054551; called by muse, mutect2
- ACACA | c.5698T>C p.Y1900H | Missense Mutation (SNP) | VAF 72/459 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MALRD1 | c.2576G>T p.C859F | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTMR6 | c.329T>G p.F110C | Missense Mutation (SNP) | VAF 13/337 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRXL2A | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- RAPGEF1 | c.2751G>A p.M917I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- ZNF26 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2
- ABRA | c.687G>A p.E229= | Silent (SNP) | VAF 86/204 reads (42%) | catalogued as COSV61732358, COSV61732643; called by muse, mutect2, varscan2
- ALPK2 | c.5760G>A p.T1920= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as rs762342746, COSV64492873; called by muse, mutect2, varscan2
- CASP10 | c.195C>T p.L65= | Silent (SNP) | VAF 10/196 reads (5%) | catalogued as COSV53776715, COSV99629303; called by muse, mutect2
- CCNI2 | c.718C>T p.L240= | Silent (SNP) | VAF 50/239 reads (21%) | catalogued as COSV101107875; called by muse, mutect2, varscan2
- COBL | c.3351C>T p.I1117= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as COSV104371485; called by muse, mutect2
- DNAH17 | c.10983C>T p.L3661= | Silent (SNP) | VAF 89/222 reads (40%) | catalogued as rs371320018; called by muse, mutect2, varscan2
- DNAJB8 | c.96C>T p.P32= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs753376929, COSV59878614; called by muse, mutect2, varscan2
- FRY | c.4824G>A p.P1608= | Silent (SNP) | VAF 44/297 reads (15%) | catalogued as rs763652703, COSV100969994, COSV66569861; called by muse, mutect2, varscan2
- GDF5 | c.483G>A p.P161= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs752789551, COSV65501445; ClinVar: uncertain significance; called by muse, mutect2
- IRAG1 | c.2055C>A p.L685= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as COSV70210821; called by muse, mutect2, varscan2
- LAT | c.417G>A p.S139= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs146679097; called by mutect2, varscan2
- LPA | c.4239G>C p.S1413= | Silent (SNP) | VAF 287/1379 reads (21%) | catalogued as rs535318353, COSV60301457, COSV60313816; called by muse, mutect2, varscan2
- NIBAN1 | c.1827G>A p.L609= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as rs1290634958, COSV62284574; called by muse, mutect2, varscan2
- NMI | c.48G>A p.S16= | Silent (SNP) | VAF 66/160 reads (41%) | catalogued as rs148602363; called by muse, mutect2, varscan2
- NPC1 | c.2325G>A p.Q775= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as COSV99341839; called by muse, mutect2
- PASD1 | c.675C>T p.Y225= | Silent (SNP) | VAF 138/352 reads (39%) | catalogued as rs773316022, COSV100949570; called by muse, mutect2
- SLC44A1 | c.951C>T p.T317= | Silent (SNP) | VAF 356/3175 reads (11%) | catalogued as rs770733177, COSV100570643; called by muse, mutect2, varscan2
- SYNE1 | c.21294C>T p.S7098= (on ENST00000367255 / NM_182961.4; = p.S7027= on NM_033071.3) | Silent (SNP) | VAF 22/798 reads (3%) | catalogued as COSV55134458; called by muse, mutect2
- SYNE1 | c.10260G>A p.A3420= (on ENST00000367255 / NM_182961.4; = p.A3427= on NM_033071.3) | Silent (SNP) | VAF 78/396 reads (20%) | catalogued as rs145287138; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- ZDBF2 | c.6645T>C p.I2215= | Silent (SNP) | VAF 26/167 reads (16%) | catalogued as COSV65625591; called by muse, mutect2, varscan2
- ZNF26 | c.792G>A p.G264= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- BACE2 | c.312+12393G>A | Intron (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- EIF5AL1 | c.*3306C>T | 3'UTR (SNP) | VAF 7/30 reads (23%) | catalogued as rs3827877; called by muse, mutect2, varscan2
- EIPR1 | c.516+5463A>G | Intron (SNP) | VAF 19/278 reads (7%) | called by muse, mutect2
- FLRT2 | c.*581G>A | 3'UTR (SNP) | VAF 18/99 reads (18%) | catalogued as rs1274337223, COSV100420605; called by muse, mutect2, varscan2
- MLLT11 | c.*706_*718del | 3'UTR (DEL) | VAF 14/111 reads (13%) | called by mutect2, pindel, varscan2
- ROBO1 | c.173-79534A>T | Intron (SNP) | VAF 11/38 reads (29%) | catalogued as COSV101459216; called by muse, mutect2, varscan2
